MMRF case MMRF_2116 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6a7edfbd-b367-4c26-96f8-cb62c7c0fe5c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.0 years (20,805 days); ISS stage: I; Days to last known disease status: 821 days (2.2 years); Days to last follow up: 821 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 226 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 303 days; Days to treatment end: 487 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 631 days (1.7 years); Days to treatment end: 639 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 729 days (2.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 821.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 3.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 49 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 11.3 g/dL; Glucose 9.13 mmol/L.
- Day 99 (ECOG 1): M Protein 1.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 20.7 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 4.62 mmol/L.
- Day 183 (ECOG 1): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 6.77 mmol/L.
- Day 281: M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.2 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.55 mmol/L.
- Day 393 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.68 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 491 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.17 mmol/L.
- Day 575 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 631 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 6.81 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 729 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 8.05 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -4: Weight: 108 kg; Height: 186 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2116_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2116_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
